Gene-level copy-number profile of tumor specimen TCGA-85-A4CL-01A from TCGA case TCGA-85-A4CL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.7 years (24,005 days).
Specimen TCGA-85-A4CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2cd45648-5c6f-4957-a94a-2d0b13690a5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A4CL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ccbe4c2-a28f-4cdb-9b0b-958b645c58af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 17,341; copy number 2: 34,005; copy number 3: 6,761; copy number 4: 715; copy number 5: 746; copy number 6: 117; copy number 7: 2; copy number 9: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A4CL-01A-41D-A26L-01): tumor purity 0.65, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr6:53,739,266–53,924,125, 3 genes (within-gene range 0–1): AL590652.1, LRRC1, AL033384.2.
- chr8:4,496,392–4,503,392, 1 gene: AC010941.1.
- chr9:2,875,442–3,053,408, 3 genes: GPS2P1, ATP5PDP2, CARM1P1.
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.
- chr9:21,178,589–24,088,051, 63 genes (broad region; genes not listed).
- chr16:6,873,899–6,874,005, 1 gene: RNU6-457P.
- chr16:7,126,293–7,126,639, 1 gene: AC022206.1.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 898 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:17,393,505–21,602,383, 57 genes, copy number 6–9 (within-gene range 2–9): CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 6: AL136313.1.
- chr8:137,809,444–138,083,657, 2 genes, copy number 6 (within-gene range 2–6): AC046195.1, AC046195.2.
- chr9:29,824,742–30,575,012, 2 genes, copy number 7 (within-gene range 3–7): ME2P1, LINC01242.
- chr9:30,935,485–31,645,160, 8 genes, copy number 5: FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr19:27,638,483–46,828,440, 828 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
